Gene-level copy-number profile of tumor specimen TCGA-FX-A3NK-01A from TCGA case TCGA-FX-A3NK, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 53.5 years (19,533 days).
Specimen TCGA-FX-A3NK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.3b2dc5c2-f7ae-461c-ac26-7a45de2258da.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FX-A3NK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 825 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/423c2f2f-127e-4863-9c24-b3a5fcc8ba93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 9,990; copy number 2: 46,381; copy number 3: 1,671; copy number 4: 166; copy number 5: 167; copy number 6: 352; copy number 7: 132; copy number 8: 207; copy number 9: 83; copy number 10: 190; copy number 11: 57; copy number 12: 127; copy number 14: 4; copy number 15: 16; copy number 16: 5; copy number 17: 33; copy number 18: 54; copy number 20: 29; copy number 21: 6; copy number 23: 1; copy number 24: 21; copy number 29: 3; copy number 30: 12; copy number 34: 28; copy number 36: 15; copy number 42: 12; copy number 47: 3; copy number 48: 4; copy number 55: 2; copy number 56: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FX-A3NK-01A-11D-A21P-01): tumor purity 0.67, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:134,412,284–135,075,908, 12 genes: B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:5,290,480–6,238,271, 12 genes: AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3, ANO2, AC137627.1, VWF, RN7SL69P, AC005845.1, CD9, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,566 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:189,035,961–189,133,292, 2 genes, copy number 5: CLPTM1LP1, GAPDHP75.
- chr4:4,348,140–5,019,458, 11 genes, copy number 5 (within-gene range 3–5): NSG1, STX18, STX18-IT1, RPS7P15, STX18-AS1, AC092437.1, LINC01396, MSX1, LDHAP1, RN7SKP113, CYTL1.
- chr6:74,849,077–76,092,940, 27 genes, copy number 5: AL356473.1, COL12A1, COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P.
- chr6:81,491,439–117,645,087, 483 genes, copy number 6–12 (broad region; genes not listed).
- chr6:125,979,812–153,427,154, 448 genes, copy number 5–20 (broad region; genes not listed).
- chr8:82,033,533–83,408,900, 10 genes, copy number 7: AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419.
- chr8:99,613,783–99,895,121, 6 genes, copy number 5: RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1.
- chr8:100,004,583–100,024,084, 2 genes, copy number 5: SNORD77B, AC021590.1.
- chr8:120,913,065–121,119,754, 1 gene, copy number 5 (within-gene range 1–5): AC068413.1.
- chr11:101,765,935–103,479,863, 49 genes, copy number 5 (within-gene range 2–5): AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1.
- chr12:3,606,633–3,764,819, 1 gene, copy number 6 (within-gene range 3–6): CRACR2A.
- chr12:3,726,222–5,244,199, 39 genes, copy number 6 (within-gene range 0–6): RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443.
- chr12:57,693,955–58,813,060, 34 genes, copy number 10–36: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:68,805,011–70,243,379, 33 genes, copy number 7–34 (within-gene range 2–37): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1.
- chr12:72,431,722–72,432,075, 1 gene, copy number 34: H3P35.
- chr12:73,820,315–74,402,600, 4 genes, copy number 48 (within-gene range 2–48): LINC02882, AC136188.1, LINC02394, AC090502.3.
- chr12:76,259,836–76,559,809, 4 genes, copy number 17: LNCOG, RN7SKP172, BBS10, OSBPL8.
- chr12:76,660,405–76,880,352, 6 genes, copy number 21: AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1.
- chr12:77,219,603–79,452,008, 14 genes, copy number 9–56 (within-gene range 2–56): LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1.
- chr12:80,099,537–80,380,879, 1 gene, copy number 42 (within-gene range 2–42): OTOGL.
- chr12:80,343,515–80,937,925, 11 genes, copy number 42: RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618.
- chr12:81,378,042–81,556,637, 1 gene, copy number 17 (within-gene range 2–17): AC069228.1.
- chr12:81,868,368–83,661,719, 15 genes, copy number 23–36: AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1.
- chr12:87,746,567–87,753,447, 3 genes, copy number 47: AC079598.4, CYCSP30, AC079598.2.
- chr12:89,010,681–90,300,974, 26 genes, copy number 6–29: LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1, LINC02392.
- chr13:67,266,845–73,661,891, 56 genes, copy number 5–6 (within-gene range 2–6): RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1, KLHL1, RNY3P10, PSMC1P13, ATXN8OS, AL160391.1, RNU6-54P, AL445264.1, MTCL1P1, LINC00348, RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393.
- chr13:80,697,177–81,115,295, 4 genes, copy number 5 (within-gene range 2–5): AL590807.1, ARF4P4, LINC00377, DPPA3P3.
- chr15:88,252,730–89,202,355, 26 genes, copy number 6 (within-gene range 3–6): NTRK3-AS1, MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN, HAPLN3, MFGE8, AC067805.1, KRT18P47, AC107954.1, AC013565.2, AC013565.1, AC013565.3, ABHD2, RNU7-195P, HMGB1P8.
- chr15:96,756,987–99,733,561, 58 genes, copy number 5–6: FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4.
- chr19:2,630,715–2,815,807, 11 genes, copy number 8: MIR7850, AC092068.1, AC092068.3, AC006538.3, DIRAS1, AC006538.2, AC006538.4, AC006538.1, SLC39A3, SGTA, THOP1.
- chr19:5,294,247–5,294,696, 1 gene, copy number 7: AC005790.1.
- chr19:6,952,500–6,997,872, 1 gene, copy number 9 (within-gene range 2–9): ADGRE4P.
- chr19:7,005,012–8,175,567, 62 genes, copy number 9–17 (broad region; genes not listed).
- chr19:9,323,772–9,407,055, 5 genes, copy number 8 (within-gene range 3–8): ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3.
- chr19:9,466,355–11,197,791, 94 genes, copy number 8–18 (within-gene range 2–18) (broad region; genes not listed).
- chr19:12,965,159–13,633,025, 16 genes, copy number 9 (within-gene range 2–9): DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A.

Autosomal genes at a single copy (total copy number 1): 7,603. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
